Somatic mutation profile of tumor specimen TARGET-30-PASTGD-01A (aliquot TARGET-30-PASTGD-01A-01D) from TARGET case TARGET-30-PASTGD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.5 years (926 days).
Specimen TARGET-30-PASTGD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3317e661-12bf-4b0a-a03a-33d271a43c99.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASTGD-10A (Blood Derived Normal), aliquot TARGET-30-PASTGD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c6ecd1c-a30d-4176-b124-0aa86d4402ac

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH4 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52917056, COSV52922000; called by muse, mutect2, varscan2
- PC | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV63081920, COSV63083371; called by muse, mutect2, varscan2
